Somatic mutation profile of tumor specimen TCGA-41-6646-01A (aliquot TCGA-41-6646-01A-11D-1845-08) from TCGA case TCGA-41-6646, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.0 years (26,667 days).
Specimen TCGA-41-6646-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06e38797-21c2-42cb-ad0d-4f70f88445d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-6646-10A (Blood Derived Normal), aliquot TCGA-41-6646-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e59d3c7c-5d95-4cd1-96c5-071f5cbb3c30

The open-access MAF lists 53 somatic variants for this specimen: 45 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Nonsense Mutation 7, Silent 4, RNA 2, Frame Shift Del 2, In Frame Del 2, Intron 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD3 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56676061; called by muse, mutect2, varscan2
- ARHGEF17 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.003); catalogued as COSV55231091; called by muse, mutect2, varscan2
- ATOX1 | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs748703620, COSV57440033; called by muse, mutect2
- CARD10 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs768052242, COSV52655294; called by muse, mutect2, varscan2
- CFAP47 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs746688244, COSV52882671; called by muse, mutect2, varscan2
- COX10 | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762976026, COSV55403943; called by muse, mutect2, varscan2
- CREB3L4 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs762042967, COSV55131447; called by muse, mutect2, varscan2
- DHX34 | c.1840G>A p.V614I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs746433421, COSV100169663, COSV60894878; called by muse, mutect2, varscan2
- DLGAP2 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1440754174, COSV70096445; called by muse, mutect2, varscan2
- DOCK4 | c.1473T>G p.H491Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70317538; called by muse, mutect2, varscan2
- EIF3B | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); catalogued as COSV62803082, COSV62803546; called by muse, mutect2, varscan2
- ELK4 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747854041, COSV56983819; called by muse, mutect2, varscan2
- EPS8L1 | c.1574G>A p.G525E (on ENST00000201647 / NM_133180.3; = p.G398E on NM_017729.3) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777892829, COSV52381118; called by muse, mutect2, varscan2
- FGG | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV60194923; called by muse, mutect2, varscan2
- GAL3ST4 | c.163T>A p.S55T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV52784665; called by muse, mutect2, varscan2
- GLYATL1 | c.213C>A p.Y71* (on ENST00000317391 / NM_001354699.1; = p.Y102* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV55608091; called by muse, mutect2, varscan2
- HNRNPDL | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55022365; called by muse, mutect2, varscan2
- IDNK | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778813883, COSV52891247; called by muse, mutect2, varscan2
- IRGC | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs752810297, COSV54984590; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs962850363, COSV56618103; called by muse, mutect2, varscan2
- MRPL55 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs145809265; called by muse, mutect2, varscan2
- NADK2 | c.1296_1298del p.E432del (on ENST00000381937 / NM_001085411.3; = p.E269del on NM_153013.4) | In Frame Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs761701214; called by pindel, varscan2
- NF1 | c.5443C>T p.Q1815* (on ENST00000358273 / NM_001042492.3; = p.Q1794* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 79/135 reads (59%) | catalogued as CD1415197, CM950848, COSV62198350; called by muse, mutect2, varscan2
- NPHP1 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 64/212 reads (30%) | catalogued as rs367600757; called by muse, mutect2, varscan2
- NUDCD1 | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53455594; called by muse, mutect2, varscan2
- OR5W2 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs1484851487, COSV60615289; called by muse, mutect2, varscan2
- PIK3R2 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs763521018, COSV55847394; called by muse, mutect2
- PLCL1 | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868552410, COSV101407023, COSV70822134; called by muse, mutect2, varscan2
- RECQL | c.393T>C p.D131= | Splice Region (SNP) | VAF 25/82 reads (30%) | catalogued as rs781458665, COSV59084562; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.113); catalogued as COSV63675528, COSV63684932; called by muse, mutect2, varscan2
- SERPINA11 | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV58241493; called by muse, mutect2, varscan2
- SHROOM3 | c.2152C>T p.R718W | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs774215303, COSV56026251, COSV99934987; called by muse, mutect2, varscan2
- SIGLEC12 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.486); catalogued as rs141817270; called by muse, mutect2, varscan2
- SLC5A1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 84/149 reads (56%) | catalogued as rs202166715, CM042476, COSV56684294; called by muse, mutect2, varscan2
- SPOCK3 | c.124A>T p.K42* | Nonsense Mutation (SNP) | VAF 35/76 reads (46%) | catalogued as COSV62721926; called by muse, mutect2, varscan2
- TMEM245 | c.1630A>T p.K544* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV65822380; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as COSV54868949; called by muse, varscan2
- TRERF1 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs371824643; called by muse, mutect2, varscan2
- TRPM1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs771033080, COSV56632809; called by muse, mutect2, varscan2
- UGGT2 | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65073510; called by muse, mutect2, varscan2
- ZNF831 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64038766; called by muse, mutect2
- CLGN | c.1471del p.C491Vfs*6 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- IGHV3-30 | c.106T>A p.S36T | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PCDH19 | c.1465_1466del p.S489Lfs*33 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | called by pindel, varscan2
- SLC38A6 | c.1072_1074del p.M358del | In Frame Del (DEL) | VAF 22/76 reads (29%) | called by pindel, varscan2
- EPHA3 | c.2121G>A p.L707= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as COSV60699800; called by muse, mutect2, varscan2
- ITGA6 | c.2952C>T p.D984= (on ENST00000442250; = p.D945= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/187 reads (10%) | catalogued as COSV51221375; called by muse, mutect2
- NCKAP5 | c.1056C>T p.S352= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV58436638; called by muse, mutect2, varscan2
- NEBL | c.138G>A p.T46= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as rs752942716, COSV65799480, COSV65799571; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820973 T>C | 3'Flank (SNP) | VAF 31/69 reads (45%) | catalogued as rs759500717; called by muse, mutect2, varscan2
- ENPP2 | c.973-2005G>A | Intron (SNP) | VAF 30/133 reads (23%) | catalogued as rs759168793, COSV99307633; called by muse, mutect2, varscan2
- HERC2P3 | n.673G>C | RNA (SNP) | VAF 18/176 reads (10%) | called by muse, varscan2
- MIR551B | n.54C>T | RNA (SNP) | VAF 25/82 reads (30%) | catalogued as rs200815786; called by muse, mutect2, varscan2
